Somatic mutation profile of tumor specimen TCGA-DD-AACX-01A (aliquot TCGA-DD-AACX-01A-11D-A40R-10) from TCGA case TCGA-DD-AACX, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.6 years (24,329 days).
Specimen TCGA-DD-AACX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 147e87fa-40b0-4629-9227-cc45aa57824d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACX-10A (Blood Derived Normal), aliquot TCGA-DD-AACX-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5fabe5d-59c4-477f-8172-32788f858019

The open-access MAF lists 134 somatic variants for this specimen: 102 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 28, Nonsense Mutation 6, Frame Shift Del 4, RNA 3, Frame Shift Ins 2, In Frame Del 2, Splice Site 2, 3'Flank 1, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.104T>G p.I35S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62687967, COSV62691314, COSV62693017; called by muse, mutect2, varscan2
- ADAMTS12 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100710660; called by muse, mutect2, varscan2
- ADSL | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs914054348, COSV99342161; called by muse, mutect2, varscan2
- AFM | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99888710; called by muse, mutect2, varscan2
- AKIP1 | c.539A>C p.Y180S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214905; called by muse, mutect2, varscan2
- AL035461.3 | c.2816A>G p.Y939C | Missense Mutation (SNP) | VAF 159/204 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101125829; called by muse, mutect2, varscan2
- APOA1 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99369225; called by muse, mutect2, varscan2
- APOBEC4 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100426104, COSV58018025; called by muse, mutect2, varscan2
- ATP10B | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.426); catalogued as COSV100469308; called by muse, mutect2, varscan2
- C8A | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV100776472; called by muse, mutect2, varscan2
- CARD6 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1219414071, COSV99620630; called by muse, mutect2, varscan2
- CCND2 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV99714151; called by muse, mutect2, varscan2
- CD1B | c.18T>A p.F6L | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100939215; called by muse, mutect2, varscan2
- CD83 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100997751; called by muse, mutect2, varscan2
- CDK3 | c.662C>G p.T221R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100044335; called by muse, mutect2, varscan2
- CEP170 | c.3040A>T p.R1014* | Nonsense Mutation (SNP) | VAF 245/441 reads (56%) | catalogued as COSV100316844; called by muse, mutect2, varscan2
- CEP57L1 | c.1063T>G p.S355A | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100425789; called by muse, mutect2, varscan2
- CFAP300 | c.487A>G p.R163G | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777707051, COSV101462454; called by muse, mutect2, varscan2
- CLASP2 | c.41A>T p.Q14L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100223087; called by muse, mutect2, varscan2
- COL14A1 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99918746; called by muse, mutect2, varscan2
- CPPED1 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 29/85 reads (34%) | catalogued as rs577494472, COSV99903018; called by muse, mutect2, varscan2
- DNAH1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as COSV101325448; called by muse, mutect2, varscan2
- DNAH3 | c.4567C>T p.P1523S | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54501274; called by muse, mutect2, varscan2
- EDC3 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100165903; called by muse, mutect2, varscan2
- EDC4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/80 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99534357; called by muse, varscan2
- EIF2AK2 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs1388319008, COSV99240566; called by muse, mutect2, varscan2
- EP300 | c.7198T>A p.S2400T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.014); catalogued as COSV99608178; called by muse, mutect2, varscan2
- EPHA3 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.985); catalogued as COSV100344403; called by muse, mutect2, varscan2
- ERMARD | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 67/173 reads (39%) | catalogued as COSV100824781; called by muse, mutect2, varscan2
- FBP2 | c.812G>T p.S271I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100942105; called by muse, mutect2, varscan2
- FETUB | c.631A>T p.I211F | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99408951; called by muse, mutect2, varscan2
- FLCN | c.469_471del p.F157del | In Frame Del (DEL) | VAF 38/63 reads (60%) | catalogued as rs786203218; called by pindel, varscan2
- FLT4 | c.3219T>A p.S1073R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV99986591; called by muse, mutect2
- FNDC1 | c.4892C>A p.A1631E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99795474; called by muse, mutect2, varscan2
- FPR2 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.315); catalogued as rs1436884570, COSV100389233; called by muse, mutect2, varscan2
- FRMD6 | c.1396G>T p.E466* (on ENST00000344768 / NM_001267046.2; = p.E458* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100655706; called by muse, mutect2, varscan2
- GJD4 | c.888T>A p.S296R | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV100397164; called by muse, mutect2, varscan2
- GNAQ | c.253A>C p.T85P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV99680842; called by muse, mutect2, varscan2
- GUCA2A | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100813001; called by muse, mutect2, varscan2
- HRNR | c.6982A>G p.S2328G | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs1168763088, COSV100913301; called by muse, mutect2, varscan2
- IKZF1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV58785402; called by muse, mutect2, varscan2
- KCNH3 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99235062; called by muse, mutect2, varscan2
- KCNJ3 | c.922A>G p.M308V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV99715570; called by muse, mutect2, varscan2
- KIAA1217 | c.4202A>G p.H1401R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1445643491, COSV100286439; called by muse, mutect2, varscan2
- KIAA1549L | c.4099C>T p.P1367S (on ENST00000321505; = p.P1664S on NM_012194.3) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381286; called by muse, mutect2, varscan2
- KLHDC7B | c.1565C>A p.A522D (on ENST00000395676; = p.A1163D on NM_138433.5) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101192923; called by muse, mutect2, varscan2
- KLHL38 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV100384340, COSV100384506; called by muse, mutect2
- KRT28 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100137489; called by muse, mutect2, varscan2
- LRRN4 | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV101125425, COSV66645711; called by muse, mutect2, varscan2
- MST1R | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs148258933; called by muse, mutect2, varscan2
- MYCBP2 | c.5177A>G p.Y1726C (on ENST00000357337; = p.Y1764C on NM_015057.5) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100629926; called by muse, mutect2, varscan2
- MYO15A | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 175/244 reads (72%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1409238455, COSV99232191; called by muse, mutect2, varscan2
- NAA16 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101038302; called by muse, mutect2, varscan2
- NCDN | c.918C>G p.F306L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV100357257, COSV100357653; called by muse, mutect2, varscan2
- NCOA7 | c.360C>G p.N120K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99996859; called by muse, mutect2, varscan2
- NUP133 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772808; called by muse, mutect2, varscan2
- NUP133 | c.790G>T p.G264* | Nonsense Mutation (SNP) | VAF 43/156 reads (28%) | catalogued as COSV54575473; called by muse, mutect2, varscan2
- OR13C3 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as rs1316023606, COSV101053304; called by muse, mutect2, varscan2
- OR5D14 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100162286; called by muse, mutect2, varscan2
- PCDH15 | c.2540A>T p.D847V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218894, COSV57293739; called by muse, mutect2, varscan2
- PCDH7 | c.3175A>T p.M1059L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100688007; called by muse, mutect2, varscan2
- PCDHB16 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99501754; called by muse, mutect2, varscan2
- PDLIM4 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as rs766802234, COSV99516816; called by muse, mutect2, varscan2
- PHC2 | c.931A>C p.S311R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99930920; called by muse, mutect2, varscan2
- PMEPA1 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55695472, COSV99671860; called by muse, mutect2
- PRSS8 | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV99571332; called by muse, mutect2, varscan2
- PRUNE2 | c.7747G>A p.E2583K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV100944435; called by muse, mutect2, varscan2
- PTPRZ1 | c.3800A>T p.E1267V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV101099920; called by muse, mutect2, varscan2
- RBL2 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as COSV100043521; called by muse, mutect2, varscan2
- RETSAT | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99805978; called by muse, mutect2, varscan2
- ROBO3 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101185004; called by muse, mutect2, varscan2
- RPA2 | c.399A>T p.R133S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100536141; called by muse, mutect2, varscan2
- SDC4 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101023412; called by muse, mutect2, varscan2
- SEZ6L2 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.209); catalogued as COSV100435313; called by muse, mutect2, varscan2
- SIGLEC6 | c.1154A>C p.D385A | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.115); catalogued as COSV100585289; called by muse, mutect2, varscan2
- SLC22A16 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100397382, COSV57931620; called by muse, mutect2, varscan2
- SLC35B2 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1166721932, COSV51490031, COSV99241037; called by muse, mutect2, varscan2
- SLC47A1 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99565239; called by muse, mutect2, varscan2
- SLC7A11 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 103/211 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99763056; called by muse, mutect2, varscan2
- SLCO6A1 | c.1626G>C p.K542N | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101134221; called by muse, varscan2
- STRADA | c.1046C>T p.S349F (on ENST00000336174 / NM_001363786.1; = p.S312F on NM_153335.6) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368438, COSV99368509; called by muse, mutect2, varscan2
- SVIL | c.2159A>C p.N720T (on ENST00000355867 / NM_021738.3; = p.N326T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100881191; called by muse, mutect2, varscan2
- TAOK1 | c.1481T>G p.L494R | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.374); catalogued as COSV99913845; called by muse, mutect2, varscan2
- TBC1D25 | c.1130T>C p.F377S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100952130; called by muse, mutect2, varscan2
- TKT | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV99964957; called by muse, mutect2, varscan2
- TMEM101 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV99243773; called by muse, mutect2, varscan2
- TRIM46 | c.115A>C p.M39L | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99825911; called by muse, mutect2, varscan2
- TYSND1 | c.512C>G p.S171W | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs948148941, COSV54642621, COSV99751853; called by muse, mutect2, varscan2
- VIRMA | c.4384-2A>G p.X1462_splice | Splice Site (SNP) | VAF 23/59 reads (39%) | catalogued as COSV52590337; called by muse, mutect2, varscan2
- ZDHHC20 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.11); catalogued as rs777297294, COSV100203384; called by muse, mutect2, varscan2
- ZMAT4 | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52690768; called by muse, mutect2, varscan2
- ZNF337 | c.2206_2209del p.L736Vfs*38 | Frame Shift Del (DEL) | VAF 35/80 reads (44%) | catalogued as rs762274922; called by mutect2, pindel, varscan2
- ZNF665 | c.1813G>C p.A605P (on ENST00000600412; = p.A670P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV101128227; called by muse, mutect2, varscan2
- ZZZ3 | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100890275; called by muse, mutect2, varscan2
- BRD2 | c.1891del p.Y631Mfs*12 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | called by mutect2, pindel, varscan2
- CCDC138 | c.569_573dup p.Q192Nfs*37 | Frame Shift Ins (INS) | VAF 25/66 reads (38%) | called by mutect2, pindel, varscan2
- CEACAM1 | c.1092_1097dup p.S365_L366dup | In Frame Ins (INS) | VAF 63/146 reads (43%) | called by mutect2, pindel, varscan2
- CFP | c.967del p.E323Sfs*10 | Frame Shift Del (DEL) | VAF 41/64 reads (64%) | called by mutect2, pindel, varscan2
- KIF4B | c.3290_3295del p.K1097_C1099delinsS | In Frame Del (DEL) | VAF 95/241 reads (39%) | called by mutect2, pindel, varscan2
- LAMA1 | c.7176_7195+3del p.X2392_splice | Splice Site (DEL) | VAF 30/90 reads (33%) | called by mutect2, pindel, varscan2
- MIDEAS | c.1713del p.S572Pfs*16 | Frame Shift Del (DEL) | VAF 33/39 reads (85%) | called by mutect2, varscan2
- PUM2 | c.821_822dup p.Q275Nfs*3 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- ABCA4 | c.6417G>C p.R2139= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100933096; called by muse, mutect2, varscan2
- ARAP2 | c.141G>A p.Q47= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV100394415; called by muse, mutect2, varscan2
- CABIN1 | c.3978A>G p.S1326= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV99573043; called by muse, mutect2, varscan2
- CACNA1S | c.2997T>C p.N999= | Silent (SNP) | VAF 110/212 reads (52%) | catalogued as COSV100754887; called by muse, varscan2
- CCNL1 | c.924A>G p.V308= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV99904466; called by muse, mutect2, varscan2
- FBN2 | c.1002T>C p.C334= | Silent (SNP) | VAF 105/247 reads (43%) | catalogued as COSV99326512; called by muse, mutect2, varscan2
- FNBP4 | c.1284G>A p.V428= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as COSV55448274; called by muse, mutect2, varscan2
- GALNT10 | c.1557C>T p.T519= | Silent (SNP) | VAF 106/272 reads (39%) | catalogued as COSV99768654; called by muse, mutect2, varscan2
- GRIN2A | c.1191C>T p.S397= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs1231295919, COSV58025607, COSV58031282; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL20RA | c.450C>A p.S150= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100359895; called by muse, mutect2, varscan2
- LRRTM3 | c.42A>G p.V14= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs1449999495, COSV100791586; called by muse, mutect2, varscan2
- NDST3 | c.42A>G p.T14= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as COSV99630183; called by muse, mutect2, varscan2
- NR5A1 | c.1113C>T p.L371= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as COSV101007678, COSV101007686; called by muse, mutect2, varscan2
- OPRL1 | c.831G>A p.T277= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as rs144338110, COSV100402046; called by muse, mutect2, varscan2
- OR1L3 | c.342C>A p.L114= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100506231; called by muse, mutect2, varscan2
- PLA2G6 | c.1263C>T p.V421= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as rs375896475; called by muse, mutect2, varscan2
- RALGDS | c.1186C>T p.L396= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100924372; called by muse, mutect2, varscan2
- RUNDC3B | c.531A>C p.A177= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100406925; called by muse, mutect2, varscan2
- SLC37A2 | c.459T>C p.N153= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV100017109; called by muse, mutect2, varscan2
- SP100 | c.1839G>A p.K613= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99892926; called by muse, mutect2, varscan2
- SPEF2 | c.5307T>C p.I1769= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100288918; called by muse, mutect2, varscan2
- STAB2 | c.4011T>C p.C1337= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs755755156, COSV101185858; called by muse, mutect2
- TAF3 | c.2508C>T p.S836= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100720033; called by muse, mutect2, varscan2
- TCOF1 | c.1059G>A p.T353= (on ENST00000377797 / NM_001135243.1; = p.T276= on NM_000356.4) | Silent (SNP) | VAF 90/223 reads (40%) | catalogued as rs764909247, COSV100077217; called by muse, mutect2, varscan2
- TMC2 | c.1488C>T p.Y496= | Silent (SNP) | VAF 63/82 reads (77%) | catalogued as COSV100727501; called by muse, mutect2, varscan2
- ZC3H7B | c.303G>T p.A101= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs755858023, COSV100687235; called by muse, mutect2, varscan2
- ZFC3H1 | c.5319G>T p.G1773= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as rs748187435, COSV101110471; called by muse, mutect2, varscan2
- ZFP36L1 | c.855C>T p.S285= | Silent (SNP) | VAF 54/71 reads (76%) | catalogued as rs1031264419, COSV100322607; called by muse, mutect2, varscan2
- AGAP7P | n.795A>T | RNA (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- COPB2 | chr3:139355746 C>A | 3'Flank (SNP) | VAF 78/167 reads (47%) | catalogued as COSV100169035; called by muse, mutect2, varscan2
- MIR494 | n.58A>G | RNA (SNP) | VAF 37/48 reads (77%) | called by muse, mutect2, varscan2
- OR2W5 | n.1145A>G | RNA (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2
